Somatic mutation profile of tumor specimen TARGET-10-PASWFN-09A (aliquot TARGET-10-PASWFN-09A-01D) from TARGET case TARGET-10-PASWFN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.3 years (4,136 days).
Specimen TARGET-10-PASWFN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 484b8612-165f-4d9e-91c3-63588e325df5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASWFN-10A (Blood Derived Normal), aliquot TARGET-10-PASWFN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49f2599a-be3d-4ade-b079-087e1fbd3817

The open-access MAF lists 23 somatic variants for this specimen: 22 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 17, Frame Shift Ins 2, Silent 1, Frame Shift Del 1, In Frame Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK3 | c.1970G>A p.R657Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs758959409, COSV71685371; ClinVar: likely pathogenic; called by mutect2, varscan2
- ACAP1 | c.2078G>A p.R693Q | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs567059211, COSV50136935; called by muse, mutect2, varscan2
- CDH23 | c.5611G>A p.A1871T | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs766404226, COSV56459625, COSV56484173; called by muse, mutect2, varscan2
- CRABP1 | c.365C>T p.T122M | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as rs752894749, COSV55115564; called by muse, varscan2
- CSMD1 | c.8794C>T p.R2932W (on ENST00000520002; = p.R2931W on NM_033225.6) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs773593396, COSV59319231; called by muse, mutect2, varscan2
- DHX16 | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV64564481; called by muse, mutect2
- DPF2 | c.68A>C p.Q23P | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV52889928; called by muse, varscan2
- DYNC1H1 | c.8507G>A p.R2836K | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64138265; called by muse, mutect2, varscan2
- H1-2 | c.496_497del p.V166Nfs*6 | Frame Shift Del (DEL) | VAF 14/77 reads (18%) | catalogued as rs970660865; called by mutect2, varscan2
- JAK1 | c.2171G>A p.R724H | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61086725; called by muse, mutect2, varscan2
- MED12 | c.4543C>T p.R1515* | Nonsense Mutation (SNP) | VAF 8/10 reads (80%) | catalogued as COSV61344009; called by muse, mutect2, varscan2
- MSH6 | c.892C>G p.R298G | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs146816935, COSV52281654; ClinVar: uncertain significance; called by muse, mutect2
- NAALAD2 | c.989G>T p.R330M | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV58962181; called by muse, varscan2
- NF1 | c.823A>T p.I275F | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as rs786202464; ClinVar: uncertain significance; called by mutect2, varscan2
- NOTCH1 | c.7327_7328insCCCC p.V2443Afs*65 | Frame Shift Ins (INS) | VAF 10/40 reads (25%) | catalogued as COSV53027738, COSV53067348, COSV53079794, COSV53096969, COSV99079389; called by mutect2, varscan2
- RGPD4 | c.3344C>T p.T1115M | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758889509; called by muse, varscan2
- ACTR2 | c.357C>A p.N119K | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2
- HCFC2 | c.2323C>A p.P775T | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- LCOR | c.4484C>A p.A1495E | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.501); called by muse, mutect2
- NF1 | c.822_823insGCCTCT p.L274_I275insAS | In Frame Ins (INS) | VAF 12/76 reads (16%) | called by mutect2, varscan2
- OR52E4 | c.764C>A p.P255Q | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ORAI1 | c.479_483dup p.E162Sfs*29 | Frame Shift Ins (INS) | VAF 38/110 reads (35%) | called by mutect2, varscan2
- FBN2 | c.8595C>T p.P2865= | Silent (SNP) | VAF 31/180 reads (17%) | catalogued as rs137914321, COSV52547681; ClinVar: likely benign; called by muse, mutect2, varscan2
